Somatic mutation profile of tumor specimen TCGA-C5-A1M5-01A (aliquot TCGA-C5-A1M5-01A-11D-A13W-08) from TCGA case TCGA-C5-A1M5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 53.9 years (19,672 days).
Specimen TCGA-C5-A1M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e011172-4612-45e6-a930-bd549c08caf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1M5-10A (Blood Derived Normal), aliquot TCGA-C5-A1M5-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4f6804f-d4ef-4f70-a30f-2fc4ed4583d6

The open-access MAF lists 72 somatic variants for this specimen: 48 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 23, Nonsense Mutation 3, Splice Site 3, Frame Shift Ins 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.3016G>T p.D1006Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52198739; called by muse, mutect2, varscan2
- ADGRG7 | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.398); catalogued as rs906307924, COSV99841495; called by muse, mutect2
- AGO1 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV64594944; called by muse, mutect2, varscan2
- ATP1B4 | c.671G>A p.R224H (on ENST00000218008 / NM_001142447.3; = p.R220H on NM_012069.5) | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376908557, COSV54312056; called by muse, mutect2, varscan2
- BCAN | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs377328649, COSV61256357; called by muse, mutect2, varscan2
- CACNA1E | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62385594; called by muse, mutect2, varscan2
- CACNG3 | c.295+1G>A p.X99_splice | Splice Site (SNP) | VAF 22/53 reads (42%) | catalogued as COSV50065848; called by muse, mutect2, varscan2
- CAND1 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs767916183, COSV73338543, COSV73338602; called by muse, mutect2
- CCDC80 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV52820938; called by muse, mutect2
- DCHS1 | c.4807G>A p.V1603M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV55033826; called by muse, mutect2, varscan2
- DLL1 | c.844G>C p.G282R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64537159; called by muse, mutect2, varscan2
- DNAH5 | c.8654C>T p.T2885I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV54217284; called by muse, mutect2, varscan2
- FKBP7 | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as rs1559379796, COSV51846008; called by muse, mutect2, varscan2
- FXR1 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV59762293; called by muse, mutect2, varscan2
- GSX1 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.676); catalogued as COSV57232700; called by muse, mutect2, varscan2
- IL1A | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV54519370; called by muse, mutect2, varscan2
- ITPR2 | c.6621G>T p.M2207I | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101190147; called by muse, mutect2
- KIAA1958 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV61722963; called by muse, mutect2, varscan2
- KIF16B | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406781519, COSV100734876; called by muse, mutect2
- LRRTM1 | c.1307T>C p.I436T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV54440088; called by muse, mutect2, varscan2
- MAP2 | c.912G>A p.W304* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV52297164, COSV99561585; called by muse, mutect2
- MUC16 | c.10466C>T p.T3489I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV67458531; called by muse, mutect2
- NAA15 | c.1411-1G>A p.X471_splice | Splice Site (SNP) | VAF 10/130 reads (8%) | catalogued as COSV99649878; called by muse, mutect2
- NSG2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs772886581, COSV100292662, COSV57457448; called by muse, mutect2, varscan2
- PCDHB12 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs200444693, COSV53393233; called by muse, mutect2, varscan2
- PDGFD | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56369808; called by muse, mutect2
- PML | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765869727, COSV51444846; called by muse, mutect2, varscan2
- PRTG | c.2420G>A p.S807N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV101221478; called by muse, mutect2, varscan2
- RASGEF1A | c.1225-1G>A p.X409_splice | Splice Site (SNP) | VAF 50/126 reads (40%) | catalogued as COSV65666826; called by muse, mutect2, varscan2
- RNF123 | c.3935C>A p.S1312* | Nonsense Mutation (SNP) | VAF 32/270 reads (12%) | catalogued as COSV57538193; called by muse, mutect2, varscan2
- RUSC2 | c.4186C>T p.Q1396* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV63428312; called by muse, mutect2, varscan2
- SMARCAD1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV62773764; called by muse, mutect2, varscan2
- SMARCC2 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV57216692; called by muse, mutect2, varscan2
- SRCAP | c.7193G>A p.R2398H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52670422; called by muse, mutect2, varscan2
- STX6 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1258994929, COSV51111674; called by muse, mutect2, varscan2
- STXBP5L | c.858C>G p.F286L | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.228); catalogued as COSV99876277; called by muse, mutect2
- TENM2 | c.4706C>T p.A1569V (on ENST00000518659 / NM_001122679.2; = p.A1330V on NM_001080428.3) | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.604); catalogued as rs534289475, COSV69127408; called by muse, mutect2, varscan2
- TG | c.7466G>A p.R2489H | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as rs143135039; called by muse, mutect2, varscan2
- TICRR | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779953659, COSV51537655; called by muse, mutect2, varscan2
- TRPV6 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs150837047, COSV63891258; called by muse, mutect2, varscan2
- TTN | c.42211G>A p.E14071K (on ENST00000591111; = p.E6647K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/142 reads (12%) | PolyPhen benign (0.098); catalogued as COSV59983446; called by muse, mutect2, varscan2
- USF3 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as COSV57069804; called by muse, mutect2, varscan2
- ZCWPW2 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67498653; called by muse, mutect2, varscan2
- ZIC3 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54972586; called by muse, mutect2, varscan2
- ZSCAN5B | c.513G>C p.Q171H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV62838547, COSV62839055; called by muse, mutect2, varscan2
- ARHGAP4 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- P3H1 | c.1070dup p.R359Pfs*2 | Frame Shift Ins (INS) | VAF 58/183 reads (32%) | called by mutect2, pindel, varscan2
- SEMA6A | c.2210dup p.N737Kfs*8 | Frame Shift Ins (INS) | VAF 73/245 reads (30%) | called by mutect2, pindel, varscan2
- ATP2C1 | c.2652C>T p.L884= | Silent (SNP) | VAF 12/177 reads (7%) | catalogued as COSV100146969; called by muse, mutect2
- CADPS | c.1593C>T p.I531= | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as rs767919321, COSV51874522; called by muse, mutect2, varscan2
- DCLK1 | c.1461C>T p.D487= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs201558028; called by muse, mutect2, varscan2
- DFFB | c.147C>T p.Y49= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs200326674, COSV100138705; called by muse, mutect2, varscan2
- DGKB | c.426G>A p.L142= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV51773735; called by muse, mutect2, varscan2
- FAM186B | c.999G>A p.E333= | Silent (SNP) | VAF 77/199 reads (39%) | catalogued as COSV57721125, COSV99220828; called by muse, mutect2, varscan2
- GRM6 | c.699C>T p.F233= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs367700792; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC66 | c.18C>T p.F6= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100603086; called by muse, mutect2, varscan2
- MARK2 | c.1341C>T p.A447= (on ENST00000402010 / NM_001039469.2; = p.A446= on NM_004954.5) | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV59282244; called by muse, mutect2, varscan2
- MUC17 | c.798A>G p.S266= | Silent (SNP) | VAF 80/196 reads (41%) | catalogued as COSV60285473; called by muse, mutect2, varscan2
- MYO7B | c.384C>T p.G128= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs370063306; called by muse, mutect2, varscan2
- NFS1 | c.840C>T p.A280= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV65053683; called by muse, mutect2, varscan2
- NGF | c.171G>A p.A57= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs746837424, COSV65687423; called by muse, mutect2, varscan2
- OR5K3 | c.216C>T p.C72= | Silent (SNP) | VAF 24/448 reads (5%) | catalogued as COSV101051687; called by muse, mutect2
- PLIN4 | c.2517G>A p.T839= (on ENST00000301286; = p.T854= on NM_001367868.2) | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as rs753136433, COSV56689591; called by muse, varscan2
- RNF215 | c.978G>A p.A326= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs567963097, COSV53176605, COSV53177082; called by muse, mutect2, varscan2
- RRBP1 | c.3939C>T p.A1313= (on ENST00000377813 / NM_001365613.2; = p.A880= on NM_004587.3) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs146359410; called by muse, mutect2, varscan2
- SULT4A1 | c.412C>T p.L138= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV50780612; called by muse, mutect2, varscan2
- SUSD4 | c.1353G>A p.E451= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100663665, COSV59551721; called by muse, mutect2, varscan2
- TEKT1 | c.804G>A p.L268= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV100106387; called by muse, mutect2, varscan2
- TGOLN2 | c.771T>G p.P257= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as COSV56405766; called by muse, mutect2, varscan2
- TTPA | c.609C>T p.F203= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs758743565, COSV52646300; called by muse, mutect2, varscan2
- ZSCAN5B | c.879G>C p.L293= | Silent (SNP) | VAF 83/217 reads (38%) | catalogued as COSV61999641; called by muse, mutect2, varscan2
- ALX1 | c.*1C>T | 3'UTR (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100374399; called by muse, mutect2
